Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A3FZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A3FZ-01A (Primary Tumor).

[page 1 of 5]
Dual/Synchronous Primary - Noted		✓
	bw 11/29/11	

Collected Date & Time: _____

Results
Patient Name:

Units

Reference Range

Patient Name:

Accession No.:

S u r g P a t h F i n a l R e p o r t

Accession Number	Collected Date/Time	Received Date/Time	Pathologist
------------------	------------------------	-----------------------	-------------

Diagnosis:

- 1) OMENTUM, OMENTECTOMY
METASTATIC HIGH GRADE ENDOMETRIOID ADENOCARCINOMA
- 2) OVARY AND FALLOPIAN TUBE, RIGHT
SEROSAL METASTASIS OF HIGH GRADE ENDOMETRIOID ADENOCARCINOMA
OVARIAN HYPOPLASIA
- 3) UTERUS, SUPERCERVICAL HYSTERECTOMY
HIGH GRADE ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 3
SEE COMMENT AND PROTOCOL
- 4) CERVIX
METASTATIC HIGH GRADE ENDOMETRIOID ADENOCARCINOMA TO THE POSTERIOR
REFLECTION
- 5) OVARY AND FALLOPIAN TUBE, RIGHT
SEROSAL METASTASIS OF HIGH GRADE ENDOMETRIOID ADENOCARCINOMA
OVARIAN HYPOPLASIA
- 6) LYMPH NODES, LEFT PELVIC
NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES
SOFT TISSUE IMPLANTS OF HIGH GRADE ENDOMETRIOID ADENOCARCINOMA
- 7) LYMPH NODES, RIGHT PELVIC
NO EVIDENCE OF MALIGNANCY IN FIVE LYMPH NODES
- 8) SMALL BOWEL, SEGMENTAL RESECTION
SEROSAL METASTASIS OF HIGH GRADE ENDOMETRIOID ADENOCARCINOMA
- 9) APPENDIX
NO EVIDENCE OF MALIGNANCY
- 10) OMENTUM, OMENTECTOMY
METASTATIC HIGH GRADE ENDOMETRIOID ADENOCARCINOMA

(Electronically signed by)

Verified:

Comment:

The tumor appears to have arisen in the endometrial cavity in association with a complex hyperplasia with atypia. The tumor has then spread through

the myometrium via lymphatics with apparent area of perforation of the

Patient Name:

Accession No.:

- Surg Path Final Report

Accession Number	Collected Date/Time	Received Date/Time	Pathologist
------------------	---------------------	--------------------	-------------

myometrium and extension out into the serosa and surrounding organs with omental metastasis. The tumor is composed of solid sheets of cells with

1CD-0-3
adenocarcinoma, endometrioid, NCS 8381/3
Site: endometrium C54.1 for 11/29/14

[page 2 of 5]
Patient: _____

Page 2 of 5

I no papillary structures. There is a high mitotic index. Occasional organoid (acinar) structures can be found. To better define this tumor, also performed two immunoperoxidase stains to include ER which was positive in the complex hyperplasia of the endometrium, however, the tumor

cells which were invading are negative. A p53 stain showed diffuse positivity of the invasive tumor.

CAP Protocol:

3: ENDOMETRIUM: Hysterectomy (01/10)

SPECIMEN:

Uterine Corpus, Cervix, Right ovary, left ovary, Right falloipan tube, Left fallopian tube, Omentum, Bowel, Appenxi, Lymph nodes

PROCEDURE:

Radiacal hysterectomy, Omentectomy, Bowel resection, Appendectomy, Lymph node biopsies

LYMPH NODE SAMPLING:

Performed

Pelvic lymph nodes

SPECIMEN INTEGRITY:

Morcellated hysterectomy

*TUMOR SITE:

*Anterior endometrium

*Posterior endometrium

TUMOR SIZE:

Cannot be determined (see Comment)

HISTOLOGIC TYPE:

Endometrioid adenocarcinoma, not otherwise characterized

HISTOLOGIC GRADE:

FIGO grade 3

MYOMETRIAL INVASION:

Present

Depth of invasion: 17 mm

Myometrial thickness: 17 mm

INVOLVEMENT OF CERVIX:

Not involved

EXTENT OF INVOLVEMENT OF OTHER ORGANS:

Right ovary not involved

Left ovary not involved

Right fallopian tube involved

Left fallopian tube involved

*Right parametrium involved

*Left parametrium involved

*Omentum involved

Patient Name:

Accession No.:

S u r g P a t h F i n a l R e p o r t			
Accession Number	Collected Date/Time	Received Date/Time	Pathologist

*Other (specify): Bowel serosa

*PERITONEAL ASCITIC FLUID:

*Malignant (positive for malignancy)

LYMPH-VASCULAR INVASION:

Present

PATHOLOGIC STAGING (pTNM [FIGO]):

pT3b[IIIB]: Vaginal involvement (direct extension or metastasis) or parametrial involvement

pN0: No regional lymph node metastasis

[page 3 of 5]
Patient: _____

Page 3 of 5

Pelvic lymph nodes:

Number examined: 9

Number involved: 0

pM1 [IVB]: Distant metastasis

*Specify site(s), if known): Omentum, Bowel serosa

*ADDITIONAL PATHOLOGIC FINDINGS:

*Atypical hyperplasia

*Complex

*ANCILLARY STUDIES:

*Specify: _____ tissue

Specimen(s):

1. OMENTUM6. LEFT PELVIC LYMPH NODE2. RIGHT TUBE AND OVARY7. RIGHT
PELVIC LYMPH NODE3. UTERUS WITHOUT CERVIX8. BOWEL4. CERVIX9.
APPENDIX5. LEFT TUBE AND OVARY10. OMENTUM

Clinical Information:

Pelvic mass

Frozen Section Diagnosis:

1) Metastatic poorly differentiated carcinoma and _____ studies obtained

3) Poorly differentiated _____ endometrial with perforation of the
uterus _____

RSS/PCW

Gross Description:

1) Specimen 1 designated as "omentum" is received fresh in a container
labeled with the patient's name and medical record number and consists of
multiple fragments of omental tissue with embedded tumor which has an
aggregate measurement of 30 x 21 x 6.1 cm. A frozen section is done with
Dr. Smith and submitted in FS1A. Additional sections are submitted in
cassettes 1B & C.

Patient Name:

Accession No.:

A P - S u r g P a t h F i n a l R e p o r t			
Accession Number	Collected Date/Time	Received Date/Time	Pathologist

2) Specimen 2 designated as "right tube and ovary" is received fresh in a
container labeled with the patient's name and medical record number and
consists of a fallopian tube with fimbria attached which measures 3.5 x
0.5 cm. The adjacent ovary measures 3.2 x 1.3 x 1.1 cm. Representative
section of tube and ovary are submitted in cassette 2A.

3) Specimen 3 designated as "uterus, without cervix" is received fresh in
a container labeled with the patient's name and medical record number and
consists of a uterus with no cervix and no adnexa which measures 6 x 9 x

cm and weighs 194 grams. The serosal surface is completely covered with
shaggy tumor. Upon sectioning, the endomyometrium is completely filled
with tumor. Sections are submitted as:

FS3A & B: Frozen section

3C-I: Additional section of tumor through endomyometrium and
endocervical canal

4) Specimen 4 designated as "cervix" is received in formalin in a
container labeled with the patient's name and medical record number and
consists of a cervix which measures 4 cm in length and has a width of 2.5
cm. The external os measures 0.7 cm in width. Sections are submitted

as:

4A: Posterior reflection

4B: Anterior transformation zone

4C: Posterior transformation zone

5) Specimen 5 designated as "left tube and ovary

[page 4 of 5]
Patient: _____

Page 4 of 5

is received in formalin in a container labeled with the patient's name and medical record number and consists of a fallopian tube with fimbria attached which measures 4.5 x 0.3 cm. The adjacent ovary measures 3 x 1.4 x 1.4 cm. In the soft tissue between the tube and ovary, there appears to be tumor implant. Sections are submitted as:

5A: Left tube and ovary

5B: Possible tumor implant

6) Specimen 6 designated as "left pelvic lymph node" is received in formalin in a container labeled with the patient's name and medical record

number and consists of multiple irregular shaped fragments of yellow adipose tissue which has an aggregate measurement of 5.5 x 5.4 x 2.3 cm. The adipose tissue is covered with tumor implant. Several lymph nodes

are appreciated which range from 0.5 to 1.7 cm. Sections are submitted as:

6A: Lymph nodes

6B: One bisected node

6C: One bisected node

6D & E: Sample of tumor implants found in the adipose tissue

Patient Name:

Accession No.:

A P - S u r g P a t h F i n a l R e p o r t			
Accession Number	Collected Date/Time	Received Date/Time	Pathologist
[REDACTED]	[REDACTED]	[REDACTED]	

7) Specimen 7 designated as "right pelvic lymph node" is received in formalin in a container labeled with the patient's name and medical record

number and consists of multiple irregular shaped fragments of yellow adipose tissue which has an aggregate measurement of 4.5 x 4 x 1.5 cm. Several lymph nodes are appreciated which range from 0.4 to 1.4 cm.

Sections are submitted as:

7A: Lymph nodes

7B: One bisected node

7C: One bisected node

8) Specimen 8 designated as "bowel" is received in formalin in a container

labeled with the patient's name and medical record number and consists of a short segment of bowel which measures 5 cm in length. The attached adipose tissue is dark red in color. Representative sections are submitted in cassettes 8A & B.

9) Specimen 9 designated as "appendix" is received in formalin in a container labeled with the patient's name and medical record number and consists of a vermiform appendix with attached adipose tissue which measures 5 x 0.5 cm. The serosal surface is smooth and glistening. The lumen is devoid of substance. The proximal section is notched. Representative sections of the proximal, distal and middle of the appendix

are submitted in cassette 9A.

10) Specimen 10 designated as "omentum" is received in formalin in a container labeled with the patient's name and medical record number and consists of a large sheet of omentum with numerous tumor implants which measures 18 x 17 x 2 cm. Representative sections are submitted in cassettes 10A & B. [REDACTED]

Microscopic Description:

A microscopic exam was performed.

[page 5 of 5]
Patient: _____

Page 5 of 5

Immunoperoxidase/Special Stain Results:
ER: Positive in the endometrium in the complex hyperplasia
P53: Positive in the invasive tumor cells
Appropriate controls positive

Source: NCI Genomic Data Commons file 910fb296-d703-4e76-91ee-4dfeb3c5466f (TCGA-AX-A3FZ.4989F66F-57F8-4B1C-97DD-69F3036EB0BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).